Somatic mutation profile of tumor specimen TCGA-YL-A8SQ-01B (aliquot TCGA-YL-A8SQ-01B-11D-A377-08) from TCGA case TCGA-YL-A8SQ, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 61.6 years (22,482 days).
Specimen TCGA-YL-A8SQ-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0eea6a21-5d15-4616-90a8-e72441c89f67.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YL-A8SQ-10A (Blood Derived Normal), aliquot TCGA-YL-A8SQ-10A-01D-A37A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cc6b15b6-1b8b-49ea-838b-4b5e99a9d06f

The open-access MAF lists 33 somatic variants for this specimen: 27 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 21, Silent 6, Frame Shift Del 3, Frame Shift Ins 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRB1 | c.3535G>A p.V1179I | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.192); catalogued as rs1001081185, COSV60100861; called by muse, mutect2, varscan2
- B4GALNT1 | c.1591A>G p.T531A | Missense Mutation (SNP) | VAF 25/203 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.277); catalogued as COSV100246936; called by muse, mutect2, varscan2
- CACNA1E | c.572C>A p.A191D | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62384042, COSV62421776; called by muse, mutect2
- CD1B | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0.018); catalogued as rs137886679; called by muse, mutect2, varscan2
- CHST11 | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1348803637, COSV57983735; called by muse, mutect2
- DNAH11 | c.12317A>G p.Y4106C | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763870754, COSV100177057; called by muse, mutect2, varscan2
- DNAH5 | c.3574G>A p.V1192M | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV99444958; called by muse, mutect2, varscan2
- FAM83F | c.824T>C p.L275P | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV100328826; called by muse, mutect2
- FRAS1 | c.4508A>G p.Y1503C | Missense Mutation (SNP) | VAF 7/133 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99348168, COSV99353957; called by muse, mutect2
- KDM6A | c.3546A>G p.E1182= | Splice Region (SNP) | VAF 9/44 reads (20%) | catalogued as COSV100937899; called by muse, mutect2, varscan2
- NBEAL1 | c.7552A>G p.I2518V | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV68916582; called by muse, mutect2, varscan2
- NFRKB | c.1130C>T p.S377F (on ENST00000446488 / NM_001143835.2; = p.S402F on NM_006165.3) | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.272); catalogued as rs555836314, COSV100451781; called by muse, mutect2
- OR2G6 | c.283G>A p.G95S | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.046); catalogued as rs148238174; called by muse, mutect2, varscan2
- PIK3CD | c.562C>T p.R188W | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as rs754531708, COSV100739964, COSV100740277, COSV63130557; called by muse, varscan2
- RAB33B | c.118G>C p.G40R | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99978129; called by muse, mutect2, varscan2
- RAB5C | c.433G>C p.E145Q | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.142); catalogued as COSV100651372; called by muse, mutect2, varscan2
- RPTOR | c.1559C>T p.S520L | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs995035426, COSV60813647; called by muse, mutect2, varscan2
- TACR3 | c.680T>G p.M227R | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.547); catalogued as COSV100510075; called by muse, mutect2, varscan2
- TNFSF15 | c.538G>A p.V180I | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0.022); catalogued as COSV100928304; called by muse, mutect2, varscan2
- TRIM10 | c.150C>A p.D50E | Missense Mutation (SNP) | VAF 35/181 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0.009); catalogued as COSV100938781; called by muse, mutect2, varscan2
- UBA7 | c.2387T>G p.V796G | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100323493; called by muse, mutect2, varscan2
- ZNF616 | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs892904886, COSV100348081; called by muse, mutect2
- KMT2D | c.7056del p.P2354Lfs*30 | Frame Shift Del (DEL) | VAF 13/37 reads (35%) | called by mutect2, pindel, varscan2
- LRFN4 | c.36_37del p.S12Rfs*45 | Frame Shift Del (DEL) | VAF 9/30 reads (30%) | called by mutect2, pindel, varscan2
- SLC22A3 | c.1044del p.K349Nfs*27 | Frame Shift Del (DEL) | VAF 11/72 reads (15%) | called by mutect2, pindel, varscan2
- TTN | c.80855dup p.N26952Kfs*2 (on ENST00000591111; = p.N19528Kfs*2 on NM_003319.4) | Frame Shift Ins (INS) | VAF 19/48 reads (40%) | called by mutect2, pindel, varscan2
- UTP3 | c.806_817del p.Y269_Y272del | In Frame Del (DEL) | VAF 30/190 reads (16%) | called by mutect2, pindel
- CDH16 | c.2097C>T p.H699= | Silent (SNP) | VAF 18/78 reads (23%) | catalogued as rs147628216; called by muse, mutect2, varscan2
- FLG | c.10344C>T p.S3448= | Silent (SNP) | VAF 46/434 reads (11%) | catalogued as rs753578049, COSV100910500; called by muse, mutect2, varscan2
- GFPT2 | c.1320C>T p.R440= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as rs757240985, COSV99517275; called by muse, mutect2, varscan2
- MYRF | c.354C>T p.T118= (on ENST00000278836 / NM_001127392.3; = p.T109= on NM_013279.4) | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as rs773401678, COSV99606435; called by muse, mutect2, varscan2
- SORBS3 | c.1362G>A p.L454= | Silent (SNP) | VAF 18/100 reads (18%) | catalogued as rs747095201, COSV99530923; called by muse, mutect2, varscan2
- TTBK1 | c.2931G>A p.A977= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as rs756556063, COSV52488106; called by muse, mutect2, varscan2
